Somatic mutation profile of tumor specimen 0DLZOI from CCDI case PBBZXT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Ethmoid sinus; Age at diagnosis: 18.5 years (6,762 days).
Specimen 0DLZOI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7b3e032-507d-448b-8cac-7933059aab98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLZNE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/006b1a00-4270-4658-88ad-73f82040b043

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KNSTRN | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 229/573 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.528); catalogued as rs779056796; called by muse, varscan2
- MUC16 | c.16993A>G p.T5665A | Missense Mutation (SNP) | VAF 166/346 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as rs545985020; called by muse, varscan2
- TRIM77 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 128/962 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.087); catalogued as rs772259642, COSV68065929; called by muse, varscan2
- DCC | c.3775G>T p.A1259S | Missense Mutation (SNP) | VAF 264/692 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0.015); called by muse, varscan2
- MYOM1 | c.1621A>T p.I541F | Missense Mutation (SNP) | VAF 122/736 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, varscan2
- TRANK1 | c.2679A>T p.E893D | Missense Mutation (SNP) | VAF 132/347 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, varscan2
- SYNE1 | c.4356C>G p.G1452= (on ENST00000367255 / NM_182961.4; = p.G1459= on NM_033071.3) | Silent (SNP) | VAF 364/1032 reads (35%) | catalogued as COSV54973145; called by muse, varscan2
- DNAAF4 | c.-35A>C | 5'UTR (SNP) | VAF 32/69 reads (46%) | catalogued as rs1252376826; called by muse, varscan2
